Gene-level copy-number profile of tumor specimen ALCH-B0CC-TTP1-A from ALCHEMIST case ALCH-B0CC, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 70.0 years (25,583 days).
Specimen ALCH-B0CC-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 74ca8c4d-68c4-4320-935b-3f5f7c86650c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0CC-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/b3e66ec1-cf21-47f1-8053-ca015268fa1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 1,962; copy number 2: 48,418; copy number 3: 7,658; copy number 4: 344.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,384,487–93,385,817, 2 genes: AL137159.1, Y_RNA.
- chr1:143,784,376–143,797,108, 3 genes: AC239800.3, LINC02591, RNU1-143P.
- chr1:223,947,605–223,950,416, 1 gene: CICP5.
- chr1:223,976,146–223,976,249, 1 gene: RNU6-1319P.
- chr9:124,481,236–124,516,056, 2 genes: NR5A1, AL354979.1.
- chr20:10,875,333–10,909,279, 2 genes (within-gene range 0–1): AL050403.1, FAT1P1.
- chr22:20,129,456–20,148,007, 1 gene: ZDHHC8.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,962. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
